Surgical pathology report (de-identified scan), TCGA case TCGA-BA-5153, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-5153-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Diagnosis:

FSA: Tonsil, left, deep superior margin, biopsy.

- Invasive squamous carcinoma, moderately differentiated, keratinizing.

FSB: Tonsil, left, deep inferior margin, biopsy.

- No in situ or invasive carcinoma identified.

FSC: Tonsil, left, superior margin, biopsy.

- No in situ or invasive carcinoma identified.

FSD: Tonsil, left, anterior margin, biopsy.

- Focal dysplastic squamous epithelium in stroma, consistent with invasive squamous carcinoma, seen on permanent sections only.

FSE: Tonsil, left, posterior margin, biopsy.

- No in situ or invasive carcinoma identified.

FSF: Tonsil, left, inferior margin, biopsy.

- No in situ or invasive carcinoma identified.

G: Tonsil, left, removal.

- Invasive squamous carcinoma, estimated 2.7 cm diameter, without angiolymphatic invasion, extending to anterior, posterior, superior, inferior, and deep margins.

Intraoperative Consult Diagnosis:

A frozen section was requested

FSA1: Tonsil, left, deep superior margin, biopsy

- Invasive squamous cell carcinoma

FSB1: Tonsil, left, deep inferior margin, biopsy

- Negative for carcinoma

FSC1: Tonsil, left, superior margin, biopsy

- Negative for carcinoma

FSD1: Tonsil, left anterior margin, biopsy

- Negative for carcinoma

FSE1: Tonsil, left, posterior margin, biopsy

- Negative for carcinoma

FSF1: Tonsil, left, inferior margin, biopsy

- Negative for carcinoma

Frozen Section Pathologist:

Clinical History:

with left tonsillar cancer.

Gross Description:

[page 2 of 2]
Received are two appropriately labeled containers.

The first container is labeled FSA1-FSF1. It contains cassettes labeled case number FSA1-FSF1.

The second container is additionally labeled "G" and "left tonsil, suture superior." It contains the left tonsil which weighs 14.2 grams. It measures superiorly to inferiorly, 4.7 cm; medial to lateral, 3.1 cm; and superior to deep, 1.2 cm. A silk suture marks the superior margin. The superior margin is inked yellow. The inferior margin is inked black. The anterior margin is inked red. The deep margin is inked blue and the posterior margin is inked green.

G1 - superior margin

G2 - inferior margin

The remainder of the specimen is serially sectioned from anterior to posterior and submitted in blocks G3-G11.

Light Microscopy:

Light microscopic examination is performed

Frozen section diagnoses for specimens FSA, FSB, FSC, FSE and FSF are confirmed by permanent sections. Permanent sections of frozen section D tonsil, left anterior margin show focus suspicious for stromal invasive carcinoma. Review of the original frozen sections does not show this focus.

Histologic tumor type: squamous

Histologic grade: moderately differentiated

Tumor extent: 2.7 cm diameter

Presence/absence of CIS: present

Presence/absence of angiolymphatic space invasion: absent

Presence/absence of perineural space invasion: absent

Histologic assessment of surgical margins: all positive: Deep, Sup (G1), Inf (G2), ant (G3), and post (G11).

Lymph nodes: none sampled

AJCC staging:

pT2

pNx

pMx

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Source: NCI Genomic Data Commons file 701aea60-4e77-45ae-ab4d-4bb0997f293e (TCGA-BA-5153.6509B8C4-7507-47F8-8758-129F873BA2E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).